Gene-level copy-number profile of tumor specimen ALCH-B3ZH-TTP1-A from ALCHEMIST case ALCH-B3ZH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.4 years (21,701 days).
Specimen ALCH-B3ZH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2a96973c-87c1-416a-9ca9-c08eba6ea227.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3ZH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/77198bce-a484-478f-b0b1-8913278a144b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,717; copy number 2: 55,884; copy number 3: 751; copy number 4: 11; copy number 5: 21; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:56,805,336–56,808,148, 1 gene: CICP28.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 23 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,179,889–90,315,836, 7 genes, copy number 5: IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118.
- chr14:18,333,726–18,568,790, 6 genes, copy number 5–6: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.7, CR383656.13.
- chr21:10,413,477–13,067,033, 10 genes, copy number 5: BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P.

Autosomal genes at a single copy (total copy number 1): 722. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
